Somatic mutation profile of tumor specimen TCGA-D3-A2J7-06A (aliquot TCGA-D3-A2J7-06A-11D-A196-08) from TCGA case TCGA-D3-A2J7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.1 years (25,233 days).
Specimen TCGA-D3-A2J7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ab2ca24-bc00-46bd-9d0e-4a05de0e78e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2J7-10A (Blood Derived Normal), aliquot TCGA-D3-A2J7-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/863557e9-2406-4c77-b39f-c77493236ea1

The open-access MAF lists 408 somatic variants for this specimen: 274 protein-altering or splice-affecting, 128 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 128, Nonsense Mutation 18, Intron 3, Splice Site 2, 5'UTR 2, Splice Region 1, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CUBN | c.4459C>T p.R1487* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as rs145661597; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3381G>A p.M1127I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53962382; called by muse, mutect2, varscan2
- ACSM1 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54637289; called by muse, mutect2, varscan2
- ACSM2A | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.483); catalogued as COSV54586343; called by muse, mutect2, varscan2
- ACSS3 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54087351; called by muse, mutect2, varscan2
- ADAM19 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as rs775287603, COSV57433089; called by muse, mutect2, varscan2
- ADAM2 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as rs865998881, COSV55864411; called by muse, mutect2, varscan2
- ADAM7 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51541710; called by muse, mutect2, varscan2
- ADAMTS18 | c.2530G>A p.E844K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267604647, COSV51418100; called by muse, mutect2, varscan2
- ADAMTS20 | c.4480C>T p.Q1494* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV67129810; called by muse, mutect2, varscan2
- ADCY8 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as rs145360233, COSV53913924; called by muse, mutect2, varscan2
- ADH1B | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59297146; called by muse, mutect2, varscan2
- AKAP6 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); catalogued as COSV55219617; called by muse, mutect2, varscan2
- ALPL | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV66379948, COSV66380101; called by muse, mutect2, varscan2
- ANK1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV55877639; called by muse, mutect2
- ANK3 | c.11272G>A p.E3758K | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.115); catalogued as COSV55050686; called by muse, mutect2, varscan2
- ANKRD11 | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV99968571; called by muse, mutect2, varscan2
- ANKRD24 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV53672410; called by muse, mutect2, varscan2
- ANO4 | c.436G>A p.G146R (on ENST00000392977 / NM_001286615.2; = p.G111R on NM_178826.4) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54601763; called by muse, mutect2, varscan2
- APBA3 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV57463055; called by muse, mutect2, varscan2
- APOB | c.8725G>A p.E2909K | Missense Mutation (SNP) | VAF 153/733 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.321); catalogued as rs200824333; called by muse, mutect2, varscan2
- ARHGAP33 | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV50119696, COSV50129492; called by muse, mutect2, varscan2
- ARHGAP9 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV62723424; called by muse, mutect2, varscan2
- ARHGEF6 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51692739, COSV99166575; called by muse, mutect2, varscan2
- ARPP21 | c.2233C>G p.P745A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs758722955, COSV51801288; called by muse, varscan2
- ASAP2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs942839221, COSV55633977; called by muse, mutect2, varscan2
- ATP10D | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56709289; called by muse, mutect2, varscan2
- ATP2A3 | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV99988904; called by muse, mutect2, varscan2
- ATRNL1 | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as COSV58095710; called by muse, mutect2
- BCAT1 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV53913718, COSV99679068; called by muse, mutect2, varscan2
- BEST3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58302709; called by muse, mutect2, varscan2
- BRINP3 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 48/251 reads (19%) | catalogued as COSV66513576, COSV66524701; called by muse, mutect2, varscan2
- BSG | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61077565; called by muse, mutect2, varscan2
- C6 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs544279109, COSV54712602; called by muse, mutect2, varscan2
- CABP4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56885026; called by muse, mutect2
- CACNA1E | c.1213T>A p.S405T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV100701471; called by muse, mutect2
- CACNA1S | c.1394-1G>A p.X465_splice | Splice Site (SNP) | VAF 9/62 reads (15%) | catalogued as COSV62941121; called by muse, mutect2, varscan2
- CALB2 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs780393008, COSV56940285, COSV56942051; called by mutect2, varscan2
- CAPZA3 | c.521G>A p.W174* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as rs868817065, COSV56852732; called by muse, mutect2, varscan2
- CAVIN3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV58269251; called by muse, mutect2, varscan2
- CCNB2 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs1211667325, COSV55596089; called by muse, mutect2, varscan2
- CCNL1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV55819746; called by muse, mutect2, varscan2
- CD1A | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs1425907404, COSV56861286; called by mutect2, varscan2
- CDC42EP4 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV59963365; called by muse, varscan2
- CDS1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV55688818; called by muse, mutect2, varscan2
- CFAP58 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV63834807; called by muse, varscan2
- CHAT | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60322756; called by muse, mutect2, varscan2
- CHML | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59365507; called by muse, mutect2, varscan2
- CLSTN1 | c.272G>A p.G91E (on ENST00000377298 / NM_001009566.3; = p.G81E on NM_014944.4) | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1470611256, COSV100790496; called by muse, mutect2, varscan2
- CLVS1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1465656591, COSV57977822; called by muse, mutect2, varscan2
- CNST | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV100830018; called by muse, mutect2, varscan2
- CNTNAP4 | c.3105G>A p.M1035I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs867459784, COSV56687979; called by muse, varscan2
- COL16A1 | c.1885-1G>A p.X629_splice | Splice Site (SNP) | VAF 20/130 reads (15%) | catalogued as COSV54709157; called by muse, mutect2, varscan2
- COL4A2 | c.2669G>A p.G890E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64629970; called by muse, mutect2, varscan2
- COL6A5 | c.7331C>T p.S2444F (on ENST00000312481; = p.S2440F on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55207136; called by muse, mutect2, varscan2
- COX18 | c.574A>G p.S192G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV55720814; called by muse, mutect2, varscan2
- CPAMD8 | c.3491G>A p.R1164Q (on ENST00000651564; = p.R1117Q on NM_015692.5) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as rs1315391248, COSV71596360; called by muse, mutect2, varscan2
- CRACDL | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV67408887, COSV67409734; called by muse, mutect2, varscan2
- CREBBP | c.3329C>G p.P1110R | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52116220, COSV52129305; called by muse, mutect2, varscan2
- CSF2RA | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as COSV62625282; called by muse, mutect2, varscan2
- CSMD2 | c.7174G>A p.D2392N | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs556378681, COSV53927057; called by muse, mutect2, varscan2
- CWH43 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56935994; called by muse, mutect2, varscan2
- CYP2B6 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV57844552; called by muse, mutect2, varscan2
- CYP2C8 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV64877768; called by muse, mutect2, varscan2
- CYP4A11 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60222200; called by muse, mutect2, varscan2
- DAB2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1175572898, COSV57916008; called by muse, mutect2, varscan2
- DCN | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV50007800; called by muse, mutect2, varscan2
- DFFA | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV65477764; called by muse, mutect2, varscan2
- DLX6 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762084855, COSV50292759; called by muse, mutect2, varscan2
- DNAH11 | c.8903G>A p.W2968* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100177913; called by muse, mutect2, varscan2
- DNAH5 | c.11113C>T p.P3705S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54235434; called by muse, mutect2, varscan2
- DNAH5 | c.5297C>T p.S1766F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as COSV54224682; called by muse, mutect2
- DNAH5 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV99446267; called by muse, mutect2, varscan2
- DNAH7 | c.3832C>T p.H1278Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV56771861; called by muse, mutect2, varscan2
- DOT1L | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV67108735, COSV67109346; called by muse, mutect2, varscan2
- DPPA2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs922189877, COSV72118023; called by muse, mutect2, varscan2
- EIF2AK3 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 65/361 reads (18%) | catalogued as rs754973185, CM097405, COSV57549290; called by muse, mutect2, varscan2
- ELAVL3 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs868461722, COSV63646674; called by muse, mutect2, varscan2
- EPRS1 | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs372832109; called by muse, mutect2, varscan2
- ERC2 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1248585292, COSV55614936; called by muse, mutect2, varscan2
- ESRRG | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as rs1175042812, COSV63161834; called by muse, mutect2, varscan2
- EVC2 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747880765, COSV60390255; called by muse, mutect2, varscan2
- FABP2 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56788137; called by muse, mutect2
- FAM163A | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs145701153, COSV59205320; called by muse, mutect2, varscan2
- FBN3 | c.5845G>A p.E1949K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1328150230, COSV54464780; called by muse, varscan2
- FBXO36 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99391469; called by muse, mutect2, varscan2
- FBXO39 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV58622299; called by muse, mutect2, varscan2
- FGB | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV57417597; called by muse, mutect2, varscan2
- FLG2 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs772274448, COSV66166946; called by muse, mutect2, varscan2
- FLNC | c.6953G>A p.R2318Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs749235580, CM1512386, COSV57958447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100420246, COSV58138393; called by muse, mutect2, varscan2
- FMO2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52948588; called by muse, mutect2, varscan2
- GABRA6 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50884578; called by muse, mutect2, varscan2
- GALNT14 | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as rs35447902, COSV61107115; called by muse, mutect2, varscan2
- GCKR | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs758692756, COSV53020757; called by muse, mutect2, varscan2
- GPR157 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV66233968; called by mutect2, varscan2
- GRIN2A | c.3920C>T p.P1307L | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV58041471; called by muse, mutect2, varscan2
- GTF3C1 | c.3923C>T p.S1308F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62242395; called by muse, mutect2, varscan2
- H6PD | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV66231364; called by muse, mutect2, varscan2
- HDAC9 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.062); catalogued as COSV67776930; called by muse, mutect2, varscan2
- HERC5 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV52041458; called by muse, mutect2, varscan2
- HHIPL1 | c.1471G>A p.G491S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58089738, COSV58091601; called by muse, mutect2, varscan2
- HIP1 | c.2584T>C p.Y862H | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554490763, COSV61187933; called by muse, mutect2, varscan2
- HK1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53860601; called by muse, mutect2, varscan2
- HMCN1 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99625579; called by muse, mutect2, varscan2
- HMCN1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99625582; called by muse, mutect2, varscan2
- HTR3E | c.924C>T p.I308= (on ENST00000415389 / NM_001256613.1; = p.I323= on NM_182589.2) | Splice Region (SNP) | VAF 19/117 reads (16%) | catalogued as rs367632850; called by muse, mutect2, varscan2
- HYDIN | c.11690G>A p.G3897E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66639918; called by muse, mutect2
- ICAM4 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs564720444, COSV53425803; called by mutect2, varscan2
- IKZF1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV58788077; called by muse, mutect2, varscan2
- IL31RA | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV51682716; called by muse, mutect2, varscan2
- IL4R | c.1103C>G p.P368R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs375367781, COSV50150367; called by muse, mutect2, varscan2
- INPP4B | c.2759G>A p.G920E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310205480, COSV99523386; called by muse, mutect2, varscan2
- INPP4B | c.2758G>A p.G920R | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99523389; called by muse, mutect2, varscan2
- IRX5 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.078); catalogued as COSV58059331; called by muse, mutect2
- KCNJ5 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267602775, COSV57967673; called by muse, mutect2, varscan2
- KDF1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs145915640; called by muse, mutect2, varscan2
- KDM5A | c.1241C>G p.S414C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV101238660; called by muse, mutect2, varscan2
- KEAP1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50308918; called by muse, mutect2, varscan2
- KIAA1217 | c.5365G>A p.D1789N | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV56818876; called by muse, mutect2, varscan2
- KIF4B | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV70530146; called by muse, mutect2, varscan2
- KIF4B | c.2614G>A p.G872R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV70530147; called by muse, mutect2, varscan2
- KL | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV66309156; called by muse, mutect2, varscan2
- KLKB1 | c.415A>C p.K139Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.662); catalogued as COSV52996781; called by muse, mutect2, varscan2
- KRT13 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV55840421; called by muse, varscan2
- KRT31 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV52436185; called by muse, mutect2, varscan2
- KRT37 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56656939; called by muse, mutect2, varscan2
- KRT6C | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52878469; called by muse, mutect2, varscan2
- KRT71 | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as rs1565601408, COSV57291484; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV59968133; called by muse, mutect2, varscan2
- L3MBTL4 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99527844; called by muse, mutect2
- LCP2 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1234333977, COSV50453690, COSV50460081; called by muse, mutect2, varscan2
- LEFTY1 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.993); catalogued as COSV99686449; called by muse, mutect2, varscan2
- LIPG | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.875); catalogued as COSV54296896; called by muse, mutect2, varscan2
- LNP1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV67346962; called by muse, mutect2
- LRP4 | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV101066356; called by muse, mutect2, varscan2
- LRRC4C | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs865871663, COSV53419875, COSV53425921; called by mutect2, varscan2
- LRRTM4 | c.1711T>C p.F571L | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV69166784; called by muse, mutect2, varscan2
- LUZP2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754517210, COSV61209632; called by muse, mutect2, varscan2
- MARCHF11 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60128313; called by muse, mutect2
- MED13L | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1201515238, COSV56123423, COSV99928762; called by muse, mutect2, varscan2
- MEST | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 79/521 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV56228965; called by muse, mutect2, varscan2
- MET | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV59263736; called by muse, mutect2, varscan2
- MGAM | c.4212T>A p.N1404K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV72074970; called by muse, mutect2, varscan2
- MICALL2 | c.2708C>T p.S903F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as rs368188264; called by muse, mutect2, varscan2
- MISP | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV53121152; called by muse, mutect2, varscan2
- MKI67 | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.037); catalogued as rs756991287, COSV64075271; called by muse, mutect2, varscan2
- MON2 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs1429424470, COSV54809692; called by muse, mutect2, varscan2
- MRPS9 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs781724583, COSV51520418; called by muse, mutect2, varscan2
- MS4A6E | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV55727278, COSV55727342; called by muse, mutect2, varscan2
- MTCL1 | c.3961C>T p.P1321S (on ENST00000306329 / NM_001378206.1; = p.P1002S on NM_015210.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as COSV60403506; called by muse, mutect2, varscan2
- MUC16 | c.26537C>T p.S8846L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs144604762, COSV67476106; called by muse, mutect2, varscan2
- MUC16 | c.18329G>A p.R6110K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV67476110; called by muse, mutect2
- MUC16 | c.15173C>T p.T5058I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.106); catalogued as COSV101198703; called by muse, mutect2, varscan2
- MXRA5 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV54240220; called by muse, mutect2, varscan2
- MYH4 | c.2499G>A p.W833* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV55117430; called by muse, mutect2, varscan2
- NAV3 | c.5435T>A p.L1812* (on ENST00000397909 / NM_001024383.2; = p.L1790* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV57091024; called by muse, mutect2, varscan2
- NHLRC3 | c.898A>T p.S300C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV65463114; called by muse, mutect2, varscan2
- NLRP1 | c.2176C>T p.R726W | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs776245016, COSV52569845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP13 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs544413027, COSV61619947; called by muse, mutect2, varscan2
- OR10G2 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs775281568, COSV73390410; called by muse, mutect2, varscan2
- OR10K2 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1433599585, COSV100149658, COSV59221726; called by muse, mutect2, varscan2
- OR10Z1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.579); catalogued as COSV63525446; called by muse, mutect2, varscan2
- OR2A25 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV68717294, COSV68717296; called by muse, mutect2, varscan2
- OR2A5 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs149614119, COSV68738535; called by muse, mutect2, varscan2
- OR2A5 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201237598; called by muse, mutect2, varscan2
- OR2L2 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV63549966, COSV63555592; called by muse, mutect2, varscan2
- OR4K1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs147347995, COSV53460876; called by muse, mutect2, varscan2
- OR5AS1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57981336; called by muse, mutect2, varscan2
- OR5T2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57589845; called by muse, mutect2, varscan2
- OR6C70 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs767288966, COSV59244972; called by muse, mutect2, varscan2
- OR9Q1 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142831243; called by muse, mutect2, varscan2
- OSBPL11 | c.2211G>A p.W737* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV56173895; called by muse, mutect2, varscan2
- P2RX5 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); catalogued as COSV56592589, COSV99835979; called by muse, mutect2, varscan2
- PACS1 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV57698445; called by muse, mutect2, varscan2
- PAH | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61014891; called by muse, mutect2, varscan2
- PAPPA | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs776051066, COSV60286626; called by muse, mutect2, varscan2
- PARP16 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752090645, COSV56035752; called by muse, mutect2, varscan2
- PATZ1 | c.1961C>T p.S654F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56744471, COSV56744774; called by muse, mutect2, varscan2
- PCDH15 | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.955); catalogued as COSV64695014; called by muse, mutect2, varscan2
- PCDH9 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs773132480, COSV60536971; called by muse, mutect2, varscan2
- PCDHA1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV65375143; called by muse, mutect2, varscan2
- PCDHA4 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as COSV63543109; called by muse, mutect2, varscan2
- PCDHA8 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.345); catalogued as COSV65338284; called by muse, mutect2, varscan2
- PCDHB5 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.012); catalogued as rs371263545, COSV50647151; called by muse, mutect2, varscan2
- PCDHGA7 | c.1443T>G p.S481R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV53976129; called by muse, mutect2, varscan2
- PDE6C | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.439); catalogued as rs750031200, COSV65116423; called by muse, mutect2, varscan2
- PDIA2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV99249426; called by muse, mutect2, varscan2
- PDIA2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV51990509, COSV99249427; called by muse, mutect2, varscan2
- PENK | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs1377419372, COSV59240662, COSV59242614; called by muse, mutect2, varscan2
- PGLYRP2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV99483831; called by muse, mutect2
- PIGQ | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV50315947; called by muse, mutect2, varscan2
- PKDREJ | c.3028A>C p.T1010P | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV53550348; called by muse, mutect2, varscan2
- PKHD1L1 | c.3551C>T p.S1184L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV65742333; called by muse, mutect2, varscan2
- PLCG1 | c.2932C>T p.R978W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs755375534, COSV54818173; called by muse, mutect2, varscan2
- PLCXD3 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.973); catalogued as COSV60611626; called by muse, mutect2, varscan2
- PLOD3 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV56183856, COSV99778159; called by muse, mutect2, varscan2
- POM121C | c.3593G>A p.G1198E (on ENST00000607367; = p.G956E on NM_001099415.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV57547036; called by muse, mutect2, varscan2
- POU6F1 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs754214069, COSV61327146; called by muse, mutect2, varscan2
- PSG6 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV51834537; called by muse, mutect2, varscan2
- PSG9 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV52484024; called by muse, mutect2, varscan2
- PTPRD | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV61958749; called by muse, mutect2, varscan2
- RARS1 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51564473; called by muse, mutect2, varscan2
- RIBC2 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs775241324, COSV61581818; called by muse, mutect2, varscan2
- RNF123 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV59689027; called by muse, mutect2, varscan2
- ROBO2 | c.3913C>T p.R1305* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs1179711497, COSV59895999; called by muse, mutect2, varscan2
- ROR2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV65220735; called by muse, mutect2, varscan2
- RSPO3 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV63151630; called by muse, mutect2, varscan2
- S100A9 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237473855, COSV64199742; called by muse, mutect2
- SCN11A | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1285600333, COSV56572900; called by muse, mutect2, varscan2
- SCN7A | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV69272731; called by muse, mutect2, varscan2
- SCNN1G | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV55597297, COSV55599779; called by muse, mutect2, varscan2
- SECISBP2L | c.2221C>T p.P741S (on ENST00000559471 / NM_001193489.2; = p.P696S on NM_014701.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55935468; called by muse, mutect2, varscan2
- SERPINB7 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60533386; called by muse, mutect2, varscan2
- SERPINI2 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52987078; called by muse, mutect2
- SGSH | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as CM108825, COSV100413348; called by muse, mutect2, varscan2
- SH3BGRL3 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV53330571; called by muse, mutect2, varscan2
- SIPA1L1 | c.4976G>A p.R1659K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.024); catalogued as COSV62171278; called by muse, mutect2, varscan2
- SIRPG | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53808333; called by muse, mutect2, varscan2
- SLC22A10 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.018); catalogued as COSV60421966; called by muse, mutect2, varscan2
- SLC6A18 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238409826, COSV57252373; called by muse, mutect2, varscan2
- SLC7A10 | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53505069; called by muse, mutect2
- SLC7A10 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53505081; called by muse, varscan2
- SLC9C1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs779690767, COSV59885462; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2146G>A p.D716N (on ENST00000540229 / NM_001371097.1; = p.D655N on NM_001009562.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.354); catalogued as rs777796391, COSV67439734, COSV67445996; called by muse, mutect2, varscan2
- SLIT2 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56578920, COSV99879840; called by muse, mutect2, varscan2
- SNRNP200 | c.3887C>T p.P1296L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV60491368; called by muse, mutect2, varscan2
- SOX2 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100327276, COSV57621515; called by muse, varscan2
- SPEN | c.5130A>C p.K1710N | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV65363861; called by muse, mutect2, varscan2
- SRGAP3 | c.3157C>T p.R1053C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs1310210225, COSV64530946; called by muse, mutect2, varscan2
- ST6GAL2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | PolyPhen possibly damaging (0.491); catalogued as rs1335982644, COSV64526291; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 29/162 reads (18%) | PolyPhen probably damaging (0.999); catalogued as rs151127625; called by muse, mutect2, varscan2
- STAB2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868538787, COSV66345183; called by muse, mutect2, varscan2
- STYK1 | c.1205A>G p.E402G | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); catalogued as COSV50013828; called by muse, mutect2, varscan2
- SYTL5 | c.1487G>A p.W496* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV52902634; called by muse, varscan2
- TACC2 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.038); catalogued as COSV57755806, COSV57760978; called by muse, mutect2, varscan2
- TAOK1 | c.1018G>T p.G340C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.765); catalogued as COSV55594218; called by muse, mutect2, varscan2
- TASOR2 | c.6203C>T p.S2068F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100050992, COSV60168236; called by muse, mutect2, varscan2
- TENM1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.122); catalogued as COSV64435693; called by muse, mutect2, varscan2
- TFAP2E | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as rs1380828939, COSV64697154; called by muse, mutect2, varscan2
- TLL1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.115); catalogued as COSV50263279, COSV99286345; called by muse, mutect2, varscan2
- TMCC2 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.68); catalogued as COSV100319200; called by muse, mutect2, varscan2
- TOX2 | c.1289C>T p.P430L (on ENST00000358131 / NM_001098798.2; = p.P406L on NM_032883.3) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1326636614, COSV57889114; called by muse, mutect2
- TRIM69 | c.1292C>T p.S431F (on ENST00000329464 / NM_182985.5; = p.S272F on NM_080745.5) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV57802830; called by muse, mutect2, varscan2
- TSPAN9 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as rs774632414, COSV50722240; called by muse, mutect2, varscan2
- TTN | c.86732G>A p.G28911E (on ENST00000591111; = p.G21487E on NM_003319.4) | Missense Mutation (SNP) | VAF 74/181 reads (41%) | PolyPhen probably damaging (1); catalogued as COSV60158424; called by muse, mutect2, varscan2
- TTN | c.28847C>T p.S9616L (on ENST00000591111; = p.S8689L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | PolyPhen probably damaging (0.996); catalogued as rs764352461, COSV59947005; called by muse, mutect2, varscan2
- TTN | c.9436G>A p.D3146N (on ENST00000591111; = p.D3100N on NM_003319.4) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | PolyPhen probably damaging (0.998); catalogued as rs267599084, COSV60158471; called by muse, mutect2, varscan2
- TUBGCP6 | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs141188316; called by muse, mutect2, varscan2
- UGT2B15 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV57735244; called by muse, mutect2, varscan2
- UGT8 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV60418912; called by muse, mutect2, varscan2
- UNC79 | c.3605A>G p.N1202S (on ENST00000393151 / NM_001346218.2; = p.N1025S on NM_020818.5) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV56395106; called by muse, mutect2, varscan2
- VAC14 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55755056; called by muse, mutect2, varscan2
- VCAN | c.3763A>G p.T1255A | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV54108826; called by muse, mutect2, varscan2
- VPS13B | c.5582C>T p.S1861L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1028627487, COSV62147357; called by muse, mutect2, varscan2
- WNT10B | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as COSV56405749; called by muse, mutect2, varscan2
- WWC2 | c.1043T>A p.I348N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66714685; called by muse, mutect2, varscan2
- XDH | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65149700; called by muse, mutect2, varscan2
- XPO7 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as COSV53016551; called by muse, mutect2, varscan2
- ZBTB4 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs17854296, COSV60980966; called by muse, mutect2, varscan2
- ZCWPW1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.03); catalogued as COSV61249555, COSV61250651; called by muse, mutect2, varscan2
- ZNF267 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV56254072; called by muse, mutect2, varscan2
- ZNF331 | c.875T>A p.I292N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV53477859; called by muse, mutect2, varscan2
- ZNF418 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs371520628; called by muse, mutect2, varscan2
- ZNF527 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV62231798; called by muse, mutect2
- ZNF799 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV70122867; called by muse, varscan2
- ZNF831 | c.4367C>T p.S1456L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV64040395; called by muse, mutect2, varscan2
- ZP2 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762294906, COSV54811970, COSV99559696; called by muse, mutect2, varscan2
- EIF4G1 | c.2019dup p.G674Wfs*6 (on ENST00000346169 / NM_198241.3; = p.G478Wfs*6 on NM_004953.5) | Frame Shift Ins (INS) | VAF 32/137 reads (23%) | called by mutect2, pindel, varscan2
- IGHG1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRAMEF15 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PSMD10 | c.274del p.L92Ffs*8 | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- SPATA22 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- A4GNT | c.963G>A p.R321= | Silent (SNP) | VAF 113/487 reads (23%) | catalogued as rs774614227, COSV52629349; called by muse, mutect2, varscan2
- ABCC12 | c.771C>T p.F257= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV60917058; called by muse, mutect2, varscan2
- AC008397.2 | c.399G>A p.K133= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53207938; called by muse, varscan2
- AC011448.1 | c.363C>T p.V121= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs572316855, COSV52276558; called by muse, mutect2, varscan2
- ADCY5 | c.3312C>T p.I1104= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs774740790, COSV59200005; called by mutect2, varscan2
- ANKRD11 | c.2319C>T p.P773= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1344043663, COSV56359317; called by mutect2, varscan2
- ANKRD2 | c.60C>T p.A20= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV53968714; called by muse, mutect2, varscan2
- ASPM | c.4548C>T p.T1516= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs1355891706, COSV54132771, COSV99660903; called by muse, mutect2, varscan2
- ASTN1 | c.2151G>A p.E717= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV56074253; called by muse, mutect2, varscan2
- ATP2A3 | c.2481C>T p.A827= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99988899; called by muse, mutect2, varscan2
- AURKB | c.303C>T p.F101= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV60244966; called by muse, mutect2, varscan2
- BCDIN3D | c.867C>T p.F289= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100445479; called by muse, mutect2, varscan2
- BICC1 | c.957C>T p.H319= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV54064714, COSV99570600; called by muse, mutect2, varscan2
- BRINP2 | c.1404C>T p.H468= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV64178435; called by mutect2, varscan2
- BRINP3 | c.162C>T p.F54= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100818458; called by muse, mutect2, varscan2
- C12orf50 | c.1209G>A p.K403= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV53893611; called by muse, mutect2, varscan2
- C7 | c.726C>T p.I242= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57476240; called by muse, mutect2, varscan2
- CALHM1 | c.15C>T p.F5= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV61707864; called by muse, mutect2, varscan2
- CASKIN1 | c.2367G>A p.Q789= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV58215927; called by muse, mutect2, varscan2
- CCDC71 | c.675C>T p.P225= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs1234980011, COSV58910403; called by muse, mutect2, varscan2
- CCER1 | c.714C>T p.G238= | Silent (SNP) | VAF 50/204 reads (25%) | catalogued as COSV62647477, COSV62648849; called by muse, mutect2, varscan2
- CCKAR | c.846C>T p.L282= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV55162274; called by muse, varscan2
- CENPE | c.6372G>A p.L2124= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs777063765, COSV99477279; called by muse, mutect2, varscan2
- CHD7 | c.3087C>T p.P1029= | Silent (SNP) | VAF 32/222 reads (14%) | catalogued as COSV71112299; called by muse, varscan2
- CHRNA5 | c.1239C>T p.V413= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs867769219, COSV55139154; called by muse, mutect2
- CNR2 | c.777C>T p.F259= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV65693423; called by muse, mutect2, varscan2
- CNST | c.1134C>T p.S378= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs761010475, COSV63622777; called by muse, mutect2, varscan2
- CTNNA1 | c.663C>T p.L221= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs552540254, COSV100242318; called by muse, mutect2, varscan2
- CXCL12 | c.33C>T p.L11= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1406716052, COSV59108125; called by mutect2, varscan2
- CYP4F12 | c.495G>A p.T165= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs141478890, COSV61172332; called by muse, mutect2, varscan2
- DENND2A | c.1395C>T p.F465= | Silent (SNP) | VAF 39/261 reads (15%) | catalogued as COSV52046974, COSV52053714, COSV99326088; called by muse, mutect2, varscan2
- DLGAP3 | c.1149G>A p.K383= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV52395193, COSV99332646; called by muse, mutect2, varscan2
- DRD5 | c.1269G>A p.R423= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100431515, COSV100431612; called by muse, varscan2
- DSC2 | c.2430G>A p.R810= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs755276378, COSV51866388; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- EIF5 | c.39C>T p.F13= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV53685860, COSV99384982; called by muse, mutect2, varscan2
- ERICH3 | c.3183G>A p.R1061= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as rs755318663, COSV58610729; called by muse, mutect2, varscan2
- EXOC3L4 | c.246C>T p.S82= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV66295693; called by muse, mutect2
- FBXO36 | c.456G>A p.L152= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99391467; called by muse, mutect2, varscan2
- FCRL1 | c.1248G>A p.R416= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV63826074; called by muse, mutect2, varscan2
- GALK1 | c.765C>T p.L255= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs146095595; called by muse, varscan2
- GALNT11 | c.1506G>A p.Q502= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV57426811; called by muse, mutect2, varscan2
- GATC | c.183C>T p.I61= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV56663888; called by muse, mutect2, varscan2
- GNB5 | c.1170C>T p.T390= (on ENST00000261837 / NM_016194.4; = p.T348= on NM_006578.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs1019384653, COSV55899948; called by muse, mutect2, varscan2
- GPR37 | c.1632C>T p.V544= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV58257676; called by muse, mutect2, varscan2
- GPR50 | c.195C>T p.I65= | Silent (SNP) | VAF 80/233 reads (34%) | catalogued as COSV54440350, COSV99505669; called by muse, mutect2, varscan2
- GPRIN3 | c.1386C>T p.S462= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV60885401; called by muse, mutect2, varscan2
- H3-5 | c.222C>T p.I74= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV61187520, COSV61188302; called by muse, mutect2, varscan2
- HLCS | c.120C>T p.I40= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV60795129; called by muse, mutect2, varscan2
- IFRD2 | c.1323G>T p.S441= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57114306; called by muse, mutect2, varscan2
- IGHV1-58 | c.210C>T p.I70= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs947808103; called by muse, mutect2, varscan2
- IGKV1-16 | c.51C>T p.F17= | Silent (SNP) | VAF 13/105 reads (12%) | called by muse, varscan2
- IGSF1 | c.2508C>T p.I836= | Silent (SNP) | VAF 70/181 reads (39%) | catalogued as COSV63838365, COSV63840222; called by muse, mutect2, varscan2
- ILDR1 | c.1170G>A p.L390= (on ENST00000344209 / NM_001199799.2; = p.L346= on NM_175924.4) | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV56551134; called by muse, mutect2, varscan2
- KALRN | c.4458G>A p.P1486= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs139928910, COSV53782779; called by muse, mutect2, varscan2
- KAT6A | c.2724C>T p.A908= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV55907959; called by muse, mutect2, varscan2
- KBTBD8 | c.450G>A p.Q150= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV55126870, COSV55129756; called by muse, mutect2, varscan2
- KDM5A | c.1242C>T p.S414= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV101238659; called by muse, mutect2, varscan2
- KIF2B | c.339G>A p.T113= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs191384582, COSV52127559; called by muse, mutect2, varscan2
- KRT1 | c.1854C>T p.S618= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV52867554; called by muse, mutect2, varscan2
- L3MBTL4 | c.321G>A p.A107= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs745852553, COSV53128281; called by muse, varscan2
- LRP4 | c.3000C>T p.P1000= | Silent (SNP) | VAF 22/197 reads (11%) | catalogued as rs771548330, COSV101066357; called by muse, mutect2, varscan2
- LRRC7 | c.1113C>T p.F371= (on ENST00000651989 / NM_001370785.2; = p.F338= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV50495740; called by muse, mutect2
- MARCO | c.243C>T p.F81= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs75633112, COSV59053927; called by muse, mutect2, varscan2
- MECOM | c.1092G>A p.G364= (on ENST00000468789 / NM_001105078.4; = p.G552= on NM_004991.4) | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV52959610; called by muse, mutect2, varscan2
- MPP7 | c.945G>A p.R315= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as rs1298951588, COSV61734498; called by muse, mutect2, varscan2
- MUC16 | c.15174C>T p.T5058= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs1163721133, COSV101198702; called by muse, mutect2, varscan2
- MUC16 | c.6261G>A p.T2087= | Silent (SNP) | VAF 45/204 reads (22%) | catalogued as COSV67464231; called by muse, mutect2, varscan2
- MYH14 | c.537G>A p.E179= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs1490496002, COSV51822622; called by muse, mutect2, varscan2
- MYO18B | c.2592G>A p.E864= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV59124972, COSV59139116; called by muse, mutect2, varscan2
- NFATC2 | c.1053C>T p.F351= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV65357793; called by muse, mutect2, varscan2
- NHLRC4 | c.10C>T p.L4= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV50315919; called by muse, mutect2, varscan2
- NIN | c.1084C>T p.L362= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV55396053; called by muse, mutect2, varscan2
- OR14C36 | c.84C>T p.S28= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV100507661, COSV58601882; called by muse, mutect2, varscan2
- OR2F2 | c.786C>T p.P262= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV68832970; called by muse, mutect2, varscan2
- OR2M5 | c.306C>T p.F102= | Silent (SNP) | VAF 54/324 reads (17%) | catalogued as rs1558236298, COSV63546222; called by muse, varscan2
- OR4K2 | c.183C>T p.F61= | Silent (SNP) | VAF 24/262 reads (9%) | catalogued as COSV53848119; called by muse, mutect2
- OR5K3 | c.111C>T p.I37= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV67350283; called by muse, mutect2, varscan2
- OR7E24 | c.396C>T p.L132= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs981552223, COSV71702260; called by muse, mutect2, varscan2
- OR9A4 | c.705G>A p.R235= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as rs143629932, COSV71885478; called by muse, mutect2
- PAPPA | c.519C>T p.S173= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV60286619; called by muse, mutect2, varscan2
- PCDHA5 | c.748T>C p.L250= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV65353798; called by muse, mutect2, varscan2
- PCDHA6 | c.223C>T p.L75= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as COSV65351053, COSV65353809; called by muse, mutect2, varscan2
- PCDHB10 | c.2373C>T p.F791= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99503874; called by mutect2, varscan2
- PCDHB3 | c.2256G>A p.E752= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV99164358; called by muse, mutect2
- PCLO | c.13309C>T p.L4437= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV61645339; called by muse, mutect2
- PCSK5 | c.579G>A p.V193= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV65091537; called by muse, mutect2, varscan2
- PDE10A | c.279A>G p.E93= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100605559, COSV63099939; called by muse, mutect2, varscan2
- PDE1C | c.72C>T p.I24= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs1169149888, COSV58514631; called by muse, mutect2, varscan2
- PENK | c.459C>T p.S153= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV100152228; called by muse, mutect2, varscan2
- PHKB | c.1269C>T p.N423= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV54525656; called by muse, mutect2, varscan2
- PKDREJ | c.3537C>T p.S1179= | Silent (SNP) | VAF 50/158 reads (32%) | catalogued as COSV53550339; called by muse, mutect2, varscan2
- PLEKHG3 | c.2838C>T p.P946= (on ENST00000394691; = p.P1002= on NM_001308147.2) | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV55981155; called by muse, mutect2, varscan2
- PLK1 | c.1308C>T p.F436= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV55622824; called by muse, mutect2, varscan2
- PLOD1 | c.387G>A p.E129= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV52146358; called by muse, mutect2, varscan2
- PLXNA4 | c.840C>T p.L280= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs768862717, COSV58138324; called by mutect2, varscan2
- POTED | c.1740G>A p.T580= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- PRMT3 | c.324C>T p.S108= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV58175870; called by muse, mutect2, varscan2
- PROM2 | c.648C>T p.S216= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV58299137; called by muse, mutect2, varscan2
- RAD54L | c.489C>T p.F163= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV64336007, COSV64336383; called by muse, mutect2, varscan2
- RELN | c.5259G>A p.G1753= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59000618, COSV59013077; called by muse, mutect2, varscan2
- RIMS4 | c.588C>T p.L196= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as COSV65720024; called by muse, mutect2, varscan2
- SCN10A | c.4071C>T p.Y1357= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV71861953; called by muse, mutect2, varscan2
- SDK2 | c.5433G>A p.E1811= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV66189741; called by muse, mutect2, varscan2
- SGSH | c.540C>T p.P180= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs749721134, COSV100413346; called by mutect2, varscan2
- SH2B2 | c.1452C>T p.L484= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100159263; called by muse, mutect2, varscan2
- SIPA1L1 | c.2478C>T p.I826= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs765799285, COSV62171272; called by muse, mutect2, varscan2
- SLC39A10 | c.1314C>T p.F438= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV62768070; called by muse, mutect2, varscan2
- SON | c.4947T>G p.G1649= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV51662814; called by muse, mutect2, varscan2
- ST8SIA5 | c.1071C>T p.F357= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV59331014; called by muse, mutect2, varscan2
- SV2C | c.1362C>T p.F454= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV59223347; called by muse, mutect2, varscan2
- TENM3 | c.5001C>T p.S1667= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV69312364; called by muse, mutect2, varscan2
- THEMIS | c.69C>T p.I23= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV64072042; called by muse, mutect2, varscan2
- TMX2 | c.664C>T p.L222= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV53555080; called by muse, mutect2, varscan2
- TUBGCP2 | c.1890C>T p.I630= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV53306471; called by muse, mutect2, varscan2
- UGT2A3 | c.123C>T p.V41= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV52359588, COSV52360822; called by muse, mutect2, varscan2
- UGT2B17 | c.705G>A p.Q235= | Silent (SNP) | VAF 30/171 reads (18%) | catalogued as COSV58501238; called by muse, mutect2, varscan2
- UNC13C | c.3352C>T p.L1118= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1488907982, COSV52891458; called by muse, mutect2, varscan2
- UNC5B | c.2718C>T p.I906= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as COSV58978283; called by muse, mutect2, varscan2
- UNK | c.1890C>T p.F630= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV52885625; called by muse, mutect2, varscan2
- VPS9D1 | c.1347C>T p.P449= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV66994642; called by mutect2, varscan2
- VWA3B | c.2391C>T p.S797= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV68244170; called by muse, mutect2, varscan2
- VWCE | c.2076G>A p.R692= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV57111588, COSV57113412; called by muse, mutect2, varscan2
- WNT9A | c.708C>T p.F236= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV55295597; called by muse, mutect2, varscan2
- XPO6 | c.2397C>T p.I799= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs1401598995, COSV58968086; called by muse, mutect2, varscan2
- XPO6 | c.2178C>T p.L726= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs762223020, COSV58968105; called by muse, mutect2, varscan2
- ZC3H4 | c.3558G>A p.K1186= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1329085982, COSV53414343; called by muse, mutect2
- ZNF226 | c.1992C>T p.V664= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV56197119; called by muse, mutect2, varscan2
- ZNF608 | c.1881C>T p.S627= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs1454535336, COSV60437425; called by muse, mutect2, varscan2
- CPLANE1 | c.*2716C>T | 3'UTR (SNP) | VAF 8/61 reads (13%) | catalogued as rs751276020, COSV57065081; called by muse, mutect2, varscan2
- IFRD2 | c.-71G>A | 5'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as COSV57114316; called by muse, mutect2
- ITGB1 | c.2331+1281A>T | Intron (SNP) | VAF 25/152 reads (16%) | catalogued as COSV100171357; called by muse, mutect2, varscan2
- TAS2R38 | c.-1C>T | 5'UTR (SNP) | VAF 12/69 reads (17%) | catalogued as rs782730686, COSV101516363, COSV101516399; called by muse, mutect2, varscan2
- TTN | c.10360+4060G>A | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as COSV60356486; called by muse, mutect2
- TUFT1 | c.60+5437C>T | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100777032; called by muse, mutect2, varscan2
